Somatic mutation profile of tumor specimen TCGA-KK-A8I7-01A (aliquot TCGA-KK-A8I7-01A-21D-A364-08) from TCGA case TCGA-KK-A8I7, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.5 years (20,256 days).
Specimen TCGA-KK-A8I7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 051b7566-d3b0-49f7-9f0a-9bfb176f1205.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8I7-11A (Solid Tissue Normal), aliquot TCGA-KK-A8I7-11A-12D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52f495ef-c424-4c50-b856-a0b865501281

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANK1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.239); catalogued as COSV100904950; called by muse, mutect2
- KRT16 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 15/123 reads (12%) | catalogued as COSV100053077; called by muse, mutect2, varscan2
- MAP1A | c.2531C>T p.S844L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100288434, COSV55811857; called by muse, mutect2
- MXRA5 | c.4067G>A p.R1356H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.092); catalogued as rs151141545, COSV99479865; called by mutect2, varscan2
- NCAPD3 | c.3704G>A p.R1235Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs375438498; called by muse, mutect2, varscan2
- SMAD5 | c.922A>T p.R308* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV101548161; called by muse, varscan2
- STAG1 | c.3317T>G p.I1106S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99367319; called by muse, mutect2, varscan2
- TDP1 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100188195; called by muse, mutect2
- TMPRSS15 | c.2326C>G p.L776V | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.257); catalogued as COSV99519636; called by muse, mutect2
- ADCY6 | c.1488C>T p.S496= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100327025; called by muse, mutect2
- AKR1B15 | c.234G>A p.E78= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs1371126128, COSV101423364, COSV71153144; called by muse, mutect2, varscan2
- FAM135B | c.483G>T p.L161= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV50525839; called by muse, mutect2, varscan2
- OLFML2B | c.1434G>A p.T478= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as rs750757748, COSV54196078; called by muse, mutect2
